Somatic mutation profile of tumor specimen 0DMUZF from CCDI case PBCAUI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pituitary adenoma, NOS; Tissue or organ of origin: Pituitary gland; Age at diagnosis: 16.2 years (5,917 days).
Specimen 0DMUZF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17a29069-64db-4643-a834-a5501fd6ce1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMUXD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06e3d429-a80d-4252-8db5-db2a8bb6eccd

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Silent 2, Translation Start Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CB | c.3199G>C p.D1067H | Missense Mutation (SNP) | VAF 51/684 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56684065, COSV56687870; called by muse, mutect2
- COMMD3-BMI1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 27/305 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs953209238; called by muse, mutect2
- KIT | c.1658A>G p.Y553C | Missense Mutation (SNP) | VAF 90/781 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553891726, CM119324, COSV55390157, COSV55393817; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LINS1 | c.2089G>A p.V697I | Missense Mutation (SNP) | VAF 52/615 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs1231607252; called by muse, mutect2
- PCDHGA11 | c.1919A>C p.K640T | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV54028193; called by muse, mutect2, varscan2
- ATP1A2 | c.2575G>A p.A859T | Missense Mutation (SNP) | VAF 20/440 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.276); called by muse, mutect2
- DNAJB8 | c.323A>C p.D108A | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.082); called by muse, mutect2
- EGLN1 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 25/842 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2
- ENAH | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 15/328 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2
- HELLS | c.1105G>T p.E369* | Nonsense Mutation (SNP) | VAF 28/530 reads (5%) | called by muse, mutect2
- PTGER1 | c.730G>C p.A244P | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); called by muse, mutect2
- VPS13C | c.3994G>A p.A1332T (on ENST00000644861 / NM_020821.3; = p.A1289T on NM_017684.5) | Missense Mutation (SNP) | VAF 48/834 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2
- ZNF677 | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 24/402 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BAAT | c.264A>G p.L88= | Silent (SNP) | VAF 38/572 reads (7%) | catalogued as rs886063284; ClinVar: uncertain significance; called by muse, mutect2
- ZDHHC14 | c.1320G>A p.T440= | Silent (SNP) | VAF 43/345 reads (12%) | catalogued as rs895837087; called by muse, mutect2, varscan2
